Somatic mutation profile of tumor specimen 0DHTDY from CCDI case PBBUCM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,131 days).
Specimen 0DHTDY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 015e4318-2252-463d-9522-fa587b1b68d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHTDP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/204f449b-1d62-4cae-8377-6c61040525ec

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ORAI2 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs778950283, COSV104423023; called by muse, mutect2
- CHD7 | c.7550A>G p.K2517R | Missense Mutation (SNP) | VAF 182/508 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DONSON | c.1529A>G p.N510S | Missense Mutation (SNP) | VAF 210/517 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PTCH1 | c.3472_3490del p.I1158Ffs*27 | Frame Shift Del (DEL) | VAF 212/277 reads (77%) | called by mutect2, varscan2
- TG | c.2249G>A p.S750N | Missense Mutation (SNP) | VAF 241/774 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); called by muse, mutect2
- RPL19 | c.*74A>T | 3'UTR (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2, varscan2
